Gene-level copy-number profile of tumor specimen HTMCP-03-06-02441-01A from CGCI case HTMCP-03-06-02441, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 48.6 years (17,766 days).
Specimen HTMCP-03-06-02441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 891f0189-fb50-4bf5-820b-57f83b43e087.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02441-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/bdb16604-86ee-4a76-b871-a9a08e69930a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 18; copy number 2: 1,613; copy number 3: 6,418; copy number 4: 19,560; copy number 5: 18,077; copy number 6: 2,216; copy number 7: 3,432; copy number 8: 5,024; copy number 9: 1,220; copy number 10: 727; copy number 11: 65; copy number 13: 3.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:40,426,119–40,427,585, 1 gene (within-gene range 0–2): AC098869.2.
- chr4:186,266,189–187,060,930, 14 genes (within-gene range 0–2): F11, F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2.
- chr8:7,190,901–7,191,563, 1 gene: RPS3AP33.
- chr8:7,549,053–7,601,267, 7 genes: FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,015 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,281,462, 65 genes, copy number 11 (broad region; genes not listed).
- chr3:46,712,115–46,812,574, 2 genes, copy number 9 (within-gene range 4–9): AC109583.1, PRSS50.
- chr3:46,742,092–46,812,558, 5 genes, copy number 9 (within-gene range 4–9): PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:149,738,472–149,752,495, 1 gene, copy number 9: COMMD2.
- chr5:58,198–3,601,403, 89 genes, copy number 9–10 (broad region; genes not listed).
- chr7:38,269,491–38,300,322, 6 genes, copy number 10 (within-gene range 8–10): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr8:12,362,019–12,388,296, 3 genes, copy number 13: FAM66A, AC087203.1, AC087203.2.
- chr13:52,167,709–52,291,557, 1 gene, copy number 10 (within-gene range 8–10): AL158066.1.
- chr13:52,219,344–113,172,386, 616 genes, copy number 10 (broad region; genes not listed).
- chr13:113,399,610–114,337,626, 29 genes, copy number 9–10: ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:22,185,562–22,497,718, 46 genes, copy number 10: TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.
- chr14:57,999,735–94,675,829, 700 genes, copy number 9 (broad region; genes not listed).
- chr14:95,086,228–105,669,843, 392 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr14:105,785,505–106,062,683, 59 genes, copy number 9 (within-gene range 8–9): ATP6V1G1P1, IGHD, IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
